Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6X9, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6X9-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localization: R temporal

Diagnosis: Oligodendroglioma (grade II WHO)

Name of Pathologist:

ICD-O-3
Oligodendroglioma, grade II
9450/3
Site: Brain, supratentorial
C71.0

W 8/12/13

Source: NCI Genomic Data Commons file 6e20cf67-c968-42a7-8252-f89c35eccaec (TCGA-QH-A6X9.62469927-D0A5-4C27-9ABA-1DEFAB93B304.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).